CCDI case PBBRSA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/b5b0e9a3-9a8f-4e01-9b1f-d7dda5cb26b7

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Synovial sarcoma, NOS: ICD-O-3 morphology code: 9040/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 5.3 years (1,919 days).

Biospecimens (3 samples)
- Sample 0DFA8X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFA9B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFA9G: Tissue type: Tumor; Specimen type: Solid Tissue.
